Somatic mutation profile of tumor specimen C3N-00247-02 (aliquot CPT0089880009) from CPTAC case C3N-00247, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 77.6 years (28,330 days).
Specimen C3N-00247-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad3beaeb-7863-4654-8e7b-3ab60e0a9aba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00247-31 (Blood Derived Normal), aliquot CPT0091400002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f75c89b-b9fc-4d17-8425-661b940f65a4

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 12, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 1, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4236+1G>T p.X1412_splice | Splice Site (SNP) | VAF 9/188 reads (5%) | catalogued as rs876660674, COSV99587577; ClinVar: likely pathogenic; called by muse, mutect2
- PTEN | c.796A>T p.K266* | Nonsense Mutation (SNP) | VAF 29/396 reads (7%) | catalogued as rs1554825260, COSV64289176; ClinVar: pathogenic; called by muse, mutect2
- SLC4A4 | c.1661G>A p.R554H (on ENST00000264485 / NM_001098484.3; = p.R510H on NM_003759.4) | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908857, CM992672; ClinVar: pathogenic; called by muse, mutect2
- CFAP70 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1227482928; called by muse, mutect2
- CXCR2 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1303559548; called by muse, mutect2, varscan2
- LRRC7 | c.2186C>T p.S729L (on ENST00000651989 / NM_001370785.2; = p.S696L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99224245; called by muse, mutect2
- MXD4 | c.196C>T p.R66* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | catalogued as rs1490205079, COSV61466686; called by muse, mutect2
- SLC26A7 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV52596124; called by muse, mutect2
- SMARCA4 | c.547C>G p.Q183E | Missense Mutation (SNP) | VAF 15/456 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV60787423; called by muse, mutect2
- TIAM1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 27/364 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV54538084; called by muse, mutect2
- TMEM154 | c.392+2T>C p.X131_splice | Splice Site (SNP) | VAF 25/360 reads (7%) | catalogued as rs1413315065; called by muse, mutect2
- ASAP3 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- BHLHE41 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2
- CD40 | c.630G>C p.L210F | Missense Mutation (SNP) | VAF 22/546 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2
- COL12A1 | c.4591C>T p.Q1531* | Nonsense Mutation (SNP) | VAF 11/169 reads (7%) | called by muse, mutect2
- DST | c.13729G>C p.D4577H (on ENST00000361203 / NM_001374722.1; = p.D2165H on NM_015548.5) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- EIF4G1 | c.3781-3C>T | Splice Region (SNP) | VAF 32/375 reads (9%) | called by muse, mutect2
- EXOC6B | c.1097A>G p.N366S | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.13); called by muse, mutect2
- GSDMC | c.32A>G p.N11S | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.056); called by muse, mutect2
- ISLR2 | c.1016C>G p.S339C | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- JADE2 | c.243G>A p.W81* | Nonsense Mutation (SNP) | VAF 11/225 reads (5%) | called by muse, mutect2
- KCNJ8 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LRRK2 | c.814T>C p.C272R | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2
- MAGEL2 | c.2534C>G p.S845* | Nonsense Mutation (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- NCOA5 | c.1389G>C p.Q463H | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.068); called by muse, mutect2
- NKRF | c.1049T>A p.I350N | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGB6 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2
- PEG3 | c.1521T>A p.C507* | Nonsense Mutation (SNP) | VAF 26/304 reads (9%) | called by muse, mutect2
- PPFIA1 | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- PTPN22 | c.1637G>T p.S546I (on ENST00000359785 / NM_001193431.2; = p.S491I on NM_012411.5) | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SALL1 | c.2474C>G p.S825C | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- SNTG1 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.952); called by muse, mutect2
- SOCS5 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); called by muse, mutect2
- VMP1 | c.1129dup p.C377Lfs*9 | Frame Shift Ins (INS) | VAF 18/214 reads (8%) | called by mutect2, pindel
- ZFAND2B | c.568_571del p.I190Lfs*6 | Frame Shift Del (DEL) | VAF 45/407 reads (11%) | called by mutect2, pindel
- ZNF222 | c.771C>G p.F257L | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- AMPD3 | c.507C>T p.A169= (on ENST00000396553 / NM_001025389.2; = p.A178= on NM_000480.3) | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- ARHGEF37 | c.1917G>C p.G639= | Silent (SNP) | VAF 17/365 reads (5%) | called by muse, mutect2
- ATP6V1B1 | c.1314C>T p.L438= | Silent (SNP) | VAF 24/590 reads (4%) | called by muse, mutect2
- DMAC2 | c.180C>G p.L60= | Silent (SNP) | VAF 11/148 reads (7%) | called by muse, mutect2
- FAM193A | c.195G>A p.V65= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2, varscan2
- INHBC | c.897C>G p.L299= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- LRP4 | c.3261A>T p.G1087= | Silent (SNP) | VAF 34/470 reads (7%) | catalogued as rs1465323186; called by muse, mutect2
- LRRC53 | c.777G>A p.Q259= | Silent (SNP) | VAF 13/376 reads (3%) | called by muse, mutect2
- LRRK2 | c.588G>C p.L196= | Silent (SNP) | VAF 9/280 reads (3%) | called by muse, mutect2
- MUC16 | c.23949T>G p.P7983= | Silent (SNP) | VAF 26/241 reads (11%) | called by muse, mutect2, varscan2
- SERPINB12 | c.1104G>A p.S368= | Silent (SNP) | VAF 22/274 reads (8%) | catalogued as rs148428278; called by muse, mutect2
- SLC38A4 | c.1083G>C p.R361= | Silent (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- CRYBG1 | c.4846-326G>C | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
